Somatic mutation profile of tumor specimen TCGA-W5-AA36-01A (aliquot TCGA-W5-AA36-01A-11D-A417-09) from TCGA case TCGA-W5-AA36, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.7 years (18,882 days).
Specimen TCGA-W5-AA36-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 092759a9-c883-4c8a-ba51-40b171b78587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA36-10A (Blood Derived Normal), aliquot TCGA-W5-AA36-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/193c51aa-21f7-4bda-9c40-1c0da5079811

The open-access MAF lists 50 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 35, Silent 8, Nonsense Mutation 5, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs587783429, CM060210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs121913478, CM960653, COSV60640350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRE2 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs374432034; called by muse, mutect2, varscan2
- CCNB3 | c.2052C>A p.N684K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as rs782673169; called by muse, mutect2, varscan2
- CNOT1 | c.6890C>T p.T2297M | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs1309246092, COSV54699109; called by muse, mutect2, varscan2
- CR2 | c.1043C>A p.A348E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV65506396; called by muse, mutect2, varscan2
- DNAH17 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs371400048, COSV67749474; called by muse, mutect2, varscan2
- EEF2K | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs374450826; called by muse, mutect2, varscan2
- GCNT1 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1466845677; called by muse, mutect2, varscan2
- NLRP7 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV60182563; called by muse, mutect2, varscan2
- SCN8A | c.5674C>T p.R1892C | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282762156, COSV61977156, COSV61978992; called by muse, mutect2, varscan2
- TRPC6 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60259685; called by muse, mutect2, varscan2
- VWF | c.8194C>A p.Q2732K | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as CD013209; called by muse, mutect2, varscan2
- ZZZ3 | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.259); catalogued as COSV66231551; called by muse, mutect2, varscan2
- ARSF | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAMSAP3 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CENPI | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CSMD2 | c.3673G>T p.D1225Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EXOC3 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INPP5D | c.1158G>T p.Q386H (on ENST00000445964 / NM_001017915.3; = p.Q385H on NM_005541.5) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- KCNG1 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- KMO | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- KTN1 | c.2989_2995del p.L997Kfs*2 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | called by mutect2, varscan2
- MACF1 | c.4849C>T p.L1617F | Missense Mutation (SNP) | VAF 46/52 reads (88%) | called by muse, mutect2, varscan2
- MAGEA1 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- MAGEA1 | c.238T>G p.S80A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- MAGEL2 | c.1852C>A p.Q618K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MGA | c.2842G>T p.E948* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- MYH14 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- NAB1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NRK | c.4538C>T p.T1513I | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- OR10J3 | c.846C>G p.H282Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PCLO | c.10654C>G p.H3552D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGER4 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- RIPK2 | c.644A>T p.Y215F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SEC31A | c.2405T>G p.I802S (on ENST00000355196 / NM_001318120.1; = p.I763S on NM_016211.4) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- SGCA | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPRING1 | c.270C>A p.G90= | Splice Region (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- SYCP2L | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TTC8 | c.544G>T p.A182S (on ENST00000338104 / NM_001288781.1; = p.A192S on NM_144596.4) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.386); called by muse, mutect2
- ZFR | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NES | c.657C>T p.R219= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs767258473; called by muse, mutect2, varscan2
- NOL4 | c.75C>T p.T25= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- OR7C1 | c.624G>T p.V208= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- RTN1 | c.1257C>T p.D419= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs1482432522; called by muse, mutect2, varscan2
- SCUBE3 | c.2220C>T p.F740= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- TIMM50 | c.711G>T p.L237= | Silent (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- TRPS1 | c.759C>T p.R253= (on ENST00000220888 / NM_001330599.2; = p.R266= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.846C>T p.G282= (on ENST00000252463; = p.G337= on NM_032805.3) | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs146483483, COSV52971139; called by muse, mutect2, varscan2
